Somatic mutation profile of tumor specimen 0DLBMP from CCDI case PBBXZM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Germinoma; Tissue or organ of origin: Pineal gland; Age at diagnosis: 15.7 years (5,741 days).
Specimen 0DLBMP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef496be9-42dd-4c61-a296-58a02bbd4fa5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLBLW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8214a92-25c9-4d2e-baad-02244811ad34

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADD3 | c.1918G>T p.D640Y (on ENST00000356080 / NM_001320591.2; = p.D608Y on NM_001121.4) | Missense Mutation (SNP) | VAF 62/1342 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs1460319808; called by muse, mutect2
- PDZRN4 | c.2195A>G p.D732G (on ENST00000402685 / NM_001164595.2; = p.D474G on NM_013377.4) | Missense Mutation (SNP) | VAF 24/762 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs1205304007, COSV54194954; called by muse, mutect2
- RRAS2 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 63/329 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56329798, COSV56330700, COSV56332575; called by muse, mutect2, varscan2
- SLC26A5 | c.1724T>C p.M575T | Missense Mutation (SNP) | VAF 39/960 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs1453413896; called by muse, mutect2
- STK36 | c.2036A>G p.K679R | Missense Mutation (SNP) | VAF 32/664 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2
